Surgical pathology report (de-identified scan), TCGA case TCGA-MH-A561, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site BLN - Baylor, specimen TCGA-MH-A561-01A (Primary Tumor).

[page 1 of 2]
---- SURGICAL PATHOLOGY ----

MEDICAL RECORD | SURGICAL PATHOLOGY

PATHOLOGY REPORT

- A. BASE OF TUMOR FROM LEFT KIDNEY, FSA
B. LEFT RENAL MASS

*** SUPPLEMENTARY REPORT HAS BEEN ADDED ***
*** REFER TO BOTTOM OF REPORT ***

BRIEF CLINICAL HISTORY:

PREOPERATIVE DIAGNOSIS:
Renal Mass

OPERATIVE FINDINGS:

POSTOPERATIVE DIAGNOSIS:
Renal Mass

=====

PATHOLOGY REPORT

GROSS DESCRIPTION:

A. Received fresh from the operating room for intraoperative consultation is 0.5x0.5x0.1 cm irregular fragment of soft tissue entirely submitted in cassette FSA.

FROZEN SECTION DIAGNOSIS

FSA. LEFT KIDNEY, BASE OF TUMOR, FROZEN SECTION
- NO MALIGNANCY SEEN

B. Received is a 10.9 gram, 4.1 x 2.8 x 2.5 cm, partial nephrectomy specimen displaying a tan-brown, scabrous renal resection margin. The capsule margin is tan-white and smooth with minimal attached fat. The specimen is inked blue along the renal resection margin, black along the capsular resection margin, and serially sectioned to reveal a 1.8 x 1.8 x 1.8 cm, tan-yellow, well-circumscribed mass that grossly extends to the capsular surface. The mass is 0.2 cm from the renal resection margin. The remaining cut surface is tan-brown and unremarkable. No subsequent lesions are identified.

The specimen is submitted in its entirety sequentially in cassettes B1-B7. Please note that a representative portion of normal and tumor is taken for tissue.

MICROSCOPIC EXAM

FINAL DIAGNOSIS

A. LEFT KIDNEY, BASE OF TUMOR, FROZEN SECTION
- BENIGN KIDNEY PARENCHYMA
- NO TUMOR SEEN

B. KIDNEY, LEFT, PARTIAL NEPHRECTOMY
- PAPILLARY RENAL CELL CARCINOMA, TYPE 1, GRADE 1
(See cancer case summary and comment)
- TUMOR LIMITED TO KIDNEY

ICD-O-3

Carcinoma, papillary renal cell

Site, Kidney NOS

QID 2/15/13

826013

C64.9

[page 2 of 2]
Surgical Pathology Cancer Case Summary Based on AJCC/UICC TNM, 7th edition

- Procedure: Partial nephrectomy
- Specimen Laterality: Left
- Tumor Site: Lower pole
- Tumor Size: 1.8 cm
- Tumor Focality: Unifocal
- Macroscopic Extent of Tumor: Tumor limited to kidney
- Histologic Type: Papillary renal cell carcinoma
- Sarcomatoid Features: Not identified
- Tumor Necrosis: Not identified
- Histologic Grade: Grade 1
- Microscopic Tumor Extension: Tumor limited to kidney
- Margins: Margins uninvolved by invasive carcinoma
- Lymph-Vascular Invasion: Not identified
- Pathologic Staging: pT1a, pNx, pMx
- Pathologic Findings in Nonneoplastic Kidney:
- CHRONIC PYELONEPHRITIS

Comment: Additional sections pending to determine capsule invasiveness will be reported in an addendum.

SUPPLEMENTARY REPORT(S):

Supplementary Report Date:

*** SUPPLEMENTARY REPORT HAS BEEN ADDED/MODIFIED ***

(Added/Last released:

ADDITIONAL FINDINGS

- KIDNEY, LEFT, PARTIAL NEPHRECTOMY
- PAPILLARY ADENOMA
- NO CAPSULAR INVASION IDENTIFIED

Comment: Multiple additional section were examined. The rest of the diagnosis remains unchanged.

PATHOLOGIST

(End of report)

Site/AA Discrepancy		✓

Source: NCI Genomic Data Commons file f69c42cb-f191-4417-8d1e-fb73f3c819b9 (TCGA-MH-A561.E6F4C8E3-78E6-4E23-9812-F13879C29896.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).